CCDI case PBBVJL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/0e9b9bf9-e30d-47b2-b471-1fe884f9f515

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.1 years (1,845 days).

Biospecimens (3 samples)
- Sample 0DII33: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII3F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DII43: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
